Somatic mutation profile of tumor specimen MMRF_2397_1_BM_CD138pos (aliquot MMRF_2397_1_BM_CD138pos_T1_KHS5U_K14021) from MMRF case MMRF_2397, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.7 years (18,502 days).
Specimen MMRF_2397_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d1e3615-728d-48c5-8f42-e68d4f6c5c71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2397_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2397_1_PB_Whole_C3_KHS5U_K14020; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/550daafe-f2f6-4fee-8ee0-a097010eaa73

The open-access MAF lists 60 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 19, Missense Mutation 19, Intron 5, 3'Flank 4, Silent 4, 5'UTR 3, Nonsense Mutation 3, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX5 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs28395869; called by muse, mutect2, varscan2
- COL4A1 | c.3592G>A p.G1198R | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65428557; called by muse, mutect2, varscan2
- FBLN1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs150439157; called by muse, mutect2, varscan2
- HMCN1 | c.12350G>A p.R4117H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs146369421; called by muse, mutect2, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, varscan2
- MYO18B | c.7594C>T p.R2532* | Nonsense Mutation (SNP) | VAF 82/241 reads (34%) | catalogued as rs549856684; called by muse, mutect2, varscan2
- OTUD4 | c.433A>G p.N145D (on ENST00000447906 / NM_001366057.1; = p.N80D on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1403467848; called by muse, mutect2
- SCN1A | c.5714C>A p.P1905Q (on ENST00000303395 / NM_001202435.3; = p.P1894Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113408; called by muse, mutect2, varscan2
- TMEM94 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 45/178 reads (25%) | catalogued as rs777469062, COSV58594989, COSV58601566; called by muse, mutect2, varscan2
- ARHGAP21 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DGKK | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DNAH10 | c.12646C>G p.P4216A (on ENST00000409039; = p.P4155A on NM_207437.3) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DRG1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- GOLGA4 | c.689T>G p.L230R | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPK8IP3 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPS31 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- OR5I1 | c.99T>A p.F33L | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- PDE4D | c.1519C>G p.P507A (on ENST00000340635 / NM_001104631.2; = p.P371A on NM_006203.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PDS5B | c.4039C>T p.R1347* | Nonsense Mutation (SNP) | VAF 67/229 reads (29%) | called by muse, mutect2, varscan2
- PIPOX | c.191A>T p.Y64F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- SVIL | c.6641T>C p.F2214S (on ENST00000355867 / NM_021738.3; = p.F1788S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TH | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADRA1D | c.480C>T p.G160= | Silent (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- CHEK1 | c.969A>G p.T323= | Silent (SNP) | VAF 22/225 reads (10%) | called by muse, mutect2, varscan2
- IGLL5 | c.147C>T p.D49= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs772823018; called by muse, varscan2
- PABPC1L | c.183G>A p.Q61= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.99+923G>T | Intron (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- CDH7 | chr18:65882528 A>C | 3'Flank (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- CRLF2 | chrX:1212684 G>C | 5'Flank (SNP) | VAF 20/447 reads (4%) | called by muse, mutect2
- CYB5A | c.*206C>G | 3'UTR (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- DDX43 | chr6:73394795 C>A | 5'Flank (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- DHPS | c.*10G>T | 3'UTR (SNP) | VAF 67/251 reads (27%) | called by muse, mutect2, varscan2
- FIGN | c.*5242T>G | 3'UTR (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- GMPPB | chr3:49719906 G>T | 3'Flank (SNP) | VAF 27/150 reads (18%) | called by muse, mutect2, varscan2
- GMPPB | chr3:49719907 A>T | 3'Flank (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- GPR37L1 | c.*298G>A | 3'UTR (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- HSD17B3 | c.454-30C>A | Intron (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2, varscan2
- INTS3 | c.*993G>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- ISCU | c.419-300G>A | Intron (SNP) | VAF 20/57 reads (35%) | catalogued as rs1254314515; called by muse, mutect2, varscan2
- KPNA4 | c.*3283G>A | 3'UTR (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- LIMCH1 | c.*2067C>T | 3'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- MBNL2 | c.*454G>T | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ME2 | c.392+48A>T | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- MED4 | c.*642G>C | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3914A>C | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- OR4A19P | n.883T>C | RNA (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- PGBD5 | chr1:230322426 G>A | 3'Flank (SNP) | VAF 48/128 reads (38%) | called by muse, mutect2, varscan2
- PLCH2 | c.-2C>A | 5'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- PPFIA2 | c.304-54420del | Intron (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- RPS6KB1 | c.*3334A>C | 3'UTR (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- RUNX1 | c.-234G>A | 5'UTR (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- SCG2 | c.*216A>T | 3'UTR (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- SESTD1 | c.*5858A>G | 3'UTR (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- SLC17A8 | c.*18T>G | 3'UTR (SNP) | VAF 24/235 reads (10%) | called by muse, mutect2, varscan2
- SYS1 | c.*1353C>T | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- TMEM129 | c.-86A>C | 5'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, varscan2
- UNC5D | c.*3295A>C | 3'UTR (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- WFS1 | c.*554G>T | 3'UTR (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- ZNF516 | c.*1995C>A | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- ZNF827 | c.*639C>T | 3'UTR (SNP) | VAF 50/234 reads (21%) | catalogued as rs1346797981; called by muse, varscan2
